Surgical pathology report (de-identified scan), TCGA case TCGA-DZ-6131, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DZ-6131-01A (Primary Tumor).

[REDACTED]

[REDACTED] Surgical Pathology

[REDACTED] TCGA-DZ-6131

TISSUE DESCRIPTION:

Right kidney (15 x 8 x 6.0 cm) with attached 34.5 cm segment of ureter (together weigh 345 grams), and separately submitted right precaval lymph node.

DIAGNOSIS:

Kidney, right, nephrectomy: Grade 1 (of 4) papillary renal cell carcinoma, forming a 7.2 x 6.0 x 5.2 cm mass in the upper pole of the kidney. There is extension into perirenal fat. The ureteral and soft tissue margins are uninvolved. The collecting system is uninvolved.

Lymph nodes, right precaval, excision: A single right precaval lymph node is negative for tumor.

Source: NCI Genomic Data Commons file 49a9f0d5-4a01-48ff-87f0-e4ed5412b561 (TCGA-DZ-6131.E90E02FA-B94D-4F94-BD83-B615A0C8AD39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).